TCGA case TCGA-AC-A23G — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a721dac6-0126-476c-b2d4-2dbf7406454b

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Alive.

Diagnoses (1)
1. Lobular carcinoma, NOS: ICD-O-3 morphology code: 8520/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 76.5 years (27,934 days); Year of diagnosis: 2006; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T1c; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Inner.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 8.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin Hydrochloride; Days to treatment start: 109 days; Days to treatment end: 190 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 190 days; Days to treatment end: 220 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Days to treatment start: 237 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 330 days; Disease response: Tumor Free.
- Days to follow up: 2,248 days (6.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Positive.
- ERBB2 amplification (FISH): Positive.
- ESR1 (IHC): Positive; Test value range: 90-99%.
- PGR (IHC): Positive; Test value range: 80-89%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AC-A23G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 40 mg.
  Slide TCGA-AC-A23G-01A-01-TS1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AC-A23G-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AC-A23G-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-AC-A23G-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 75; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; First surgical procedure other: Right Total Mastectomy and Sentinel Node Biopsy; Histologic diagnosis: Infiltrating Lobular Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Margin status: Negative; Method initial path diagnosis: Core needle biopsy; Prospective collection: No; Retrospective collection: Yes; Metastatic tumor indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Inner Quadrant.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 2: Pharmaceutical therapy drug name: Adriamycin.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 4: Pharmaceutical therapy drug name: Arimidex.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,248 days; disease-specific survival: no event (censored), 2,248 days; disease-free interval: no event (censored), 2,248 days; progression-free interval: no event (censored), 2,248 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AC-A23G-01A-11D-A20R-01): tumor purity 0.22, ploidy 3.4, whole-genome doublings 1.
